Somatic mutation profile of tumor specimen MP2PRT-PAVSIT-TBP1-A (aliquot MP2PRT-PAVSIT-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVSIT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,807 days).
Specimen MP2PRT-PAVSIT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528765d2-542b-4656-99f3-e19f1476a028.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSIT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSIT-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5e61c75-601f-4748-985d-9785c965b795

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLMN | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 50/572 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV54182946; called by muse, mutect2
- ENOX1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs780047698, COSV54896327; called by muse, mutect2
- ITGAV | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs757973780, COSV53711136; called by muse, mutect2, varscan2
- LAMA1 | c.8083C>T p.R2695W | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs766071649; called by muse, mutect2
- MRGPRX3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs772433034, COSV101283498; called by muse, mutect2
- RETSAT | c.819T>G p.S273R | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99805972; called by muse, mutect2
- AL772284.1 | c.198C>T p.A66= | Silent (SNP) | VAF 80/838 reads (10%) | catalogued as rs1403085346; called by muse, mutect2
- DERPC | c.576C>T p.T192= | Silent (SNP) | VAF 47/523 reads (9%) | called by muse, mutect2
- DNAH6 | c.6303C>A p.G2101= | Silent (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- MECOM | c.693C>A p.S231= (on ENST00000468789 / NM_001105078.4; = p.S419= on NM_004991.4) | Silent (SNP) | VAF 42/511 reads (8%) | catalogued as COSV99245152; called by muse, mutect2
- WSCD1 | c.1665G>A p.T555= | Silent (SNP) | VAF 73/760 reads (10%) | catalogued as rs200065907, COSV58494303; called by muse, mutect2
